Somatic mutation profile of tumor specimen MMRF_2429_1_BM_CD138pos (aliquot MMRF_2429_1_BM_CD138pos_T1_KHS5U_L11077) from MMRF case MMRF_2429, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.0 years (25,566 days).
Specimen MMRF_2429_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fd634ae-932c-4eaf-b8c6-a297d6b95932.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2429_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2429_1_PB_Whole_C3_KHS5U_L11078; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd8e2932-5bb8-46b0-b9fc-b8a342d8e690

The open-access MAF lists 96 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 27, Silent 14, Intron 9, Nonsense Mutation 5, 5'UTR 3, 5'Flank 1, In Frame Ins 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 186/505 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF2 | c.2882C>T p.P961L (on ENST00000361247 / NM_001162383.2; = p.P933L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as rs1337712436; called by muse, mutect2, varscan2
- ATAD2B | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99476901; called by muse, mutect2
- BAZ2B | c.3518G>A p.R1173Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs201198370; called by muse, mutect2
- CCDC38 | c.1476G>A p.W492* | Nonsense Mutation (SNP) | VAF 83/187 reads (44%) | catalogued as rs552060224; called by muse, mutect2, varscan2
- CDH4 | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752665532, COSV64640865; called by muse, mutect2, varscan2
- CPNE6 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 93/146 reads (64%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as rs770549858, COSV53743923; called by muse, mutect2, varscan2
- CYP27B1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.251); catalogued as rs754435549, COSV57348171; called by muse, mutect2, varscan2
- DNAJA4 | c.611G>A p.R204H (on ENST00000343789; = p.R233H on NM_018602.3) | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs1282611988, COSV59424734; called by muse, mutect2, varscan2
- EYA4 | c.107C>A p.A36E | Missense Mutation (SNP) | VAF 49/53 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.583); catalogued as COSV62057494; called by muse, mutect2, varscan2
- GPR182 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs200478269, COSV55626192; called by muse, mutect2, varscan2
- IGHA2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs376878640; called by muse, mutect2, varscan2
- IGHD3-22 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 11/11 reads (100%) | catalogued as rs569854973; called by muse, mutect2, varscan2
- IGHD3-22 | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 11/11 reads (100%) | catalogued as rs537032089; called by muse, mutect2, varscan2
- IGHJ6 | c.6C>A p.Y2* | Nonsense Mutation (SNP) | VAF 36/74 reads (49%) | catalogued as rs377765927; called by muse, varscan2
- ITGAM | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.297); catalogued as rs776272340, COSV54941052; called by muse, varscan2
- KCNA2 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs941480281, COSV60368715, COSV60370638; called by muse, mutect2, varscan2
- KLHL7 | c.1286A>G p.N429S (on ENST00000339077 / NM_001031710.3; = p.N381S on NM_018846.5) | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.839); catalogued as rs368940209; called by muse, mutect2, varscan2
- NPHP3 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 98/264 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs200233813, COSV58129388, COSV58130515; called by muse, mutect2, varscan2
- RIMS2 | c.1411C>T p.R471W (on ENST00000666250 / NM_001348490.2; = p.R279W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/187 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566248680, COSV51698013; called by muse, mutect2, varscan2
- SMG7 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 97/187 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs138777313; called by muse, mutect2, varscan2
- TTLL13P | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs754001735, COSV60036038; called by muse, mutect2, varscan2
- AFAP1L2 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AIRE | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP26 | c.2284_2286dup p.K762dup | In Frame Ins (INS) | VAF 72/148 reads (49%) | called by pindel, varscan2
- ARHGAP9 | c.946C>T p.L316F | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF16 | c.1467G>T p.K489N | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ASTN2 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ASTN2 | c.446T>A p.M149K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- DENND4A | c.2559+2T>C p.X853_splice | Splice Site (SNP) | VAF 87/205 reads (42%) | called by muse, mutect2, varscan2
- DICER1 | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KCNH7 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MMAB | c.529A>T p.K177* | Nonsense Mutation (SNP) | VAF 80/170 reads (47%) | called by muse, mutect2, varscan2
- MUC16 | c.32716A>G p.T10906A | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); called by muse, mutect2
- OR6B3 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.62); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHAC1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 115/341 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- PCDHGA1 | c.2083G>T p.V695L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RAD51AP2 | c.1198A>T p.R400* | Nonsense Mutation (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- RBSN | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZCCHC18 | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF605 | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.3276A>G p.S1092= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as rs776646475; called by muse, mutect2, varscan2
- ARHGAP26 | c.2271G>A p.P757= | Silent (SNP) | VAF 102/172 reads (59%) | catalogued as rs781016419; called by muse, varscan2
- CEP250 | c.7071C>T p.V2357= | Silent (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- EID1 | c.108G>A p.G36= | Silent (SNP) | VAF 40/156 reads (26%) | called by muse, mutect2, varscan2
- MGAM | c.4554C>T p.R1518= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV72074716; called by muse, mutect2, varscan2
- MMP8 | c.309A>G p.P103= | Silent (SNP) | VAF 53/123 reads (43%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1038C>T p.N346= | Silent (SNP) | VAF 38/171 reads (22%) | called by muse, mutect2, varscan2
- PKLR | c.753C>T p.G251= | Silent (SNP) | VAF 63/117 reads (54%) | catalogued as rs1459538361, COSV61360629; called by muse, mutect2, varscan2
- SLC1A6 | c.751C>T p.L251= | Silent (SNP) | VAF 60/223 reads (27%) | called by muse, mutect2, varscan2
- SMIM3 | c.171T>C p.S57= | Silent (SNP) | VAF 38/131 reads (29%) | called by muse, mutect2, varscan2
- SORCS3 | c.2334A>G p.S778= | Silent (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- TIPRL | c.552G>T p.R184= | Silent (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- TMEM234 | c.117C>G p.T39= | Silent (SNP) | VAF 44/83 reads (53%) | called by muse, mutect2, varscan2
- ZMYM4 | c.1087C>T p.L363= | Silent (SNP) | VAF 73/155 reads (47%) | called by muse, mutect2, varscan2
- ACSS3 | c.*1445dup | 3'UTR (INS) | VAF 36/69 reads (52%) | catalogued as rs560434556; called by mutect2, varscan2
- AL591135.1 | n.4494C>T | RNA (SNP) | VAF 62/66 reads (94%) | catalogued as rs1320627422; called by muse, mutect2, varscan2
- ANXA4 | c.*945A>G | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- ATP5MC1 | c.-9-13del | Intron (DEL) | VAF 46/93 reads (49%) | catalogued as rs773139188; called by mutect2, pindel, varscan2
- COMMD3 | c.529-118G>C | Intron (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- COMTD1 | c.*101G>A | 3'UTR (SNP) | VAF 57/109 reads (52%) | catalogued as COSV100040845; called by muse, mutect2, varscan2
- CSMD2 | c.6862+1620C>G | Intron (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- DAZAP2 | c.*1015G>A | 3'UTR (SNP) | VAF 32/58 reads (55%) | called by muse, mutect2, varscan2
- DCC | c.*2414C>T | 3'UTR (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- EPB41L1 | c.*3286del | 3'UTR (DEL) | VAF 44/100 reads (44%) | catalogued as rs147818728; called by mutect2, varscan2
- FBXO22 | c.*34G>A | 3'UTR (SNP) | VAF 38/84 reads (45%) | called by muse, mutect2, varscan2
- FRAT1 | c.*37G>A | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- FUT4 | c.*2949A>G | 3'UTR (SNP) | VAF 26/53 reads (49%) | catalogued as rs1168961929; called by muse, mutect2, varscan2
- HEBP2 | c.*152A>T | 3'UTR (SNP) | VAF 28/33 reads (85%) | called by muse, varscan2
- KRTAP10-12 | c.*15C>T | 3'UTR (SNP) | VAF 48/150 reads (32%) | called by muse, mutect2, varscan2
- LILRA1 | c.*940dup | 3'UTR (INS) | VAF 8/36 reads (22%) | catalogued as rs1201383176; called by mutect2, varscan2
- LTBP3 | c.2353+209C>A | Intron (SNP) | VAF 38/80 reads (48%) | called by muse, varscan2
- LTBP3 | c.2353+208G>A | Intron (SNP) | VAF 40/80 reads (50%) | called by muse, varscan2
- MAP3K7 | c.*2017A>C | 3'UTR (SNP) | VAF 95/142 reads (67%) | called by muse, mutect2, varscan2
- MIS18BP1 | c.*360G>A | 3'UTR (SNP) | VAF 40/85 reads (47%) | called by muse, mutect2, varscan2
- MTMR9 | c.*3402C>T | 3'UTR (SNP) | VAF 37/38 reads (97%) | catalogued as rs1434864868; called by muse, mutect2, varscan2
- OXCT1 | c.*761G>T | 3'UTR (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- PCMTD1 | c.*2640T>C | 3'UTR (SNP) | VAF 47/176 reads (27%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-13337G>A | Intron (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- PI15 | c.*1135G>A | 3'UTR (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- PLXNA1 | c.*2304C>T | 3'UTR (SNP) | VAF 70/207 reads (34%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*2118C>A | 3'UTR (SNP) | VAF 82/244 reads (34%) | catalogued as rs1273103600; called by muse, mutect2, varscan2
- PRR16 | c.*341C>T | 3'UTR (SNP) | VAF 27/114 reads (24%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.-95C>G | 5'UTR (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2
- RAPGEF2 | c.-93T>A | 5'UTR (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2
- RBPJ | chr4:26319680 G>C | 5'Flank (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- RGP1 | c.*5202T>G | 3'UTR (SNP) | VAF 88/136 reads (65%) | called by muse, mutect2, varscan2
- SLC38A7 | c.*209G>A | 3'UTR (SNP) | VAF 28/61 reads (46%) | catalogued as rs377144499; called by muse, mutect2, varscan2
- SNX22 | c.*1370A>C | 3'UTR (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- STAU2 | c.1530+24477G>A | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as rs555312534; called by muse, mutect2, varscan2
- SUPT6H | c.-165A>T | 5'UTR (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- TRIM24 | c.*4899T>C | 3'UTR (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- TRIM32 | c.*425G>A | 3'UTR (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.10361-4189C>T | Intron (SNP) | VAF 69/148 reads (47%) | catalogued as rs753130126; called by muse, mutect2, varscan2
- UNC45A | c.2421+22C>T | Intron (SNP) | VAF 42/160 reads (26%) | catalogued as rs936801478; called by muse, mutect2, varscan2
- ZSWIM5 | c.*1229T>A | 3'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
